Surgical pathology report (de-identified scan), TCGA case TCGA-61-1911, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1911-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: RIGHT PELVIC PERITONEUM, BIOPSY –
NEGATIVE FOR TUMOR (SEE COMMENT).

PART 2: RIGHT PERICOLIC TISSUE, BIOPSY –
NEGATIVE FOR TUMOR.

PART 3: LEFT PERICOLIC GUTTER, BIOPSY –
NEGATIVE FOR TUMOR (SEE COMMENT).

PART 4: PELVIC, BIOPSY –
NEGATIVE FOR TUMOR (SEE COMMENT).

PART 5: OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY –
A. OVARY WITH HIGH-GRADE SEROUS CARCINOMA (7 CM) INVOLVING FIMBRIATED SEGMENT OF FALLOPIAN TUBE.
B. OVARIAN SURFACE INVOLVED BY TUMOR.
C. LYMPHOVASCULAR INVASION IS IDENTIFIED.
D. UNINVOLVED FALLOPIAN TUBE, HISTOLOGICALLY UNREMARKABLE.
E. RECEPTOR STUDIES: ER-POSITIVE, PR-NEGATIVE.
F. PELVIC WASH AND DIAPHRAGMATIC SCRAPINGS ARE NEGATIVE FOR TUMOR (SEE COMMENT).
G. PATHOLOGIC STAGE: T2a N0 Mx.
H. FIGO: II A.

PART 6: POST PERITONEUM, BIOPSY –
NEGATIVE FOR TUMOR

PART 7: UTERUS WITH RIGHT OVARY AND RIGHT FALLOPIAN TUBE, TOTAL ABDOMINAL HYSTERECTOMY AND RIGHT SALPINGO-OOPHORECTOMY –
A. ENDOMETRIAL POLYP.
B. INACTIVE ENDOMETRIUM.
C. CERVIX WITH SQUAMOUS METAPLASIA.
D. RIGHT OVARY AND FALLOPIAN TUBE, HISTOLOGICALLY UNREMARKABLE.

PART 8: LYMPH NODES, LEFT PELVIC, BIOPSY –
FIVE LYMPH NODES, NEGATIVE FOR METASTATIC TUMOR (0/5).

PART 9: LYMPH NODES, RIGHT PELVIC, BIOPSY –
FIVE LYMPH NODES, NEGATIVE FOR METASTATIC TUMOR (0/5).

PART 10: LYMPH NODES, LEFT PERIAORTIC, BIOPSY –
ONE LYMPH NODES, NEGATIVE FOR METASTATIC TUMOR (0/1).

PART 11: LYMPH NODES, RIGHT PERIAORTIC, BIOPSY –
TWO LYMPH NODES, NEGATIVE FOR T METASTATIC UMOR (0/2).

PART 12: OMENTUM, BIOPSY –
NEGATIVE FOR TUMOR (SEE COMMENT).

MICROSCOPIC:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Left
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 7 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Solid (3)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	> or = 25 (3)

VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Not present

MALIGNANT CELLS IN ASCITES OR

PERITONEAL WASHING:

LYMPH NODES EXAMINED: Total number of lymph nodes examined: 13

T STAGE, PATHOLOGIC: pT2a

N STAGE, PATHOLOGIC: pN0

M STAGE, PATHOLOGIC: pMx

Source: NCI Genomic Data Commons file 9f021e29-5916-4597-952f-ab0500387984 (TCGA-61-1911.BA6325B4-AF61-42CC-B84C-AACEE9D7ECC8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).